TARGET case TARGET-20-PADYMH — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/909a750c-c7d5-4a4c-8529-f86b3dba3ecb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 169 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.0 years (4,011 days); Year of diagnosis: 1996; Days to last follow up: 169 days.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: CCG2961.

Follow-up (2 entries)
- Days to follow up: 61 days; Days to first event: 61 days; First event: Induction Failure.
- Days to follow up: 169 days; Year of follow up: 1997.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Positive.
- NPM1 mutation, nos: Negative.
- NUP98–NSD1 fusion: Positive.
- WT1 mutation, nos: Positive.
- Day 0: Leukocytes 92.8 ×10³/µL; Blast Count 64%; Bone Marrow blast count 79%.

Biospecimens (1 sample)
- Sample TARGET-20-PADYMH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_LowDepthRNAseq_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 169
- WBC at Diagnosis: 92.8
- Bone marrow leukemic blast percentage (%): 79
- Peripheral blasts (%): 64
- CNS disease: No
- Chloroma: No
- FAB Category: M2
- Primary Cytogenetic Code: Other
- FLT3/ITD positive?: Yes
- FLT3/ITD allelic ratio: 0.51
- FLT3 PM: No
- NPM mutation: No
- CEBPA mutation: No
- WT1 mutation: Yes
- CR status at end of course 1: not in CR
- CR status at end of course 2: not in CR
- Risk group: High Risk
- Bone Marrow Site of Relapse/Induction Failure: Yes
- CNS Site of Relapse/Induction Failure: No
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: No
- Other Site of Relapse/Induction Failure: No
- Blast count used for RNA seq: 79
- Gene Fusion: NUP98-NSD1
